Surgical pathology report (de-identified scan), TCGA case TCGA-XR-A8TF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XR-A8TF-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0
8176/3
9/29/14

Nature of material: Liver
Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received liver segment measuring 17.0 x 12.0 x 7.5 cm and weighing 532 grams. To the cuts there is whitish and friable lesion measuring 6.5 cm in diameter, 0.3 cm away from surgical margin. The liver surface is slightly irregular.

MICROSCOPY

Expendable description.

DIAGNOSTIC

Excision product of hepatic segment:

- Hepatocellular carcinoma of hepatic type;
- Microscopically surgical margin of 0.59 cm;
- Non-neoplastic liver with moderate periportal fibrosis, but keeping preserved architecture;
- Angiolymphatic invasion undetected;
- Pathological staging: pT1 (TNM - 7th edition);
- Not observed Schistosoma mansoni eggs.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Criteria	11/8/13	Yes	No
ICD-O Discrepancy			

Source: NCI Genomic Data Commons file be1e0641-d9a6-40b7-9989-514bbd811f9d (TCGA-XR-A8TF.A0557F82-3ACC-43E5-9ED3-902BEDD36939.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).